Somatic mutation profile of tumor specimen 1c9145ad-1981-4871-aa7e-8b11de (aliquot 1c9145ad-1981-4871-aa7e-8b11de_D6) from CPTAC case 17OV001, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage III.
Specimen 1c9145ad-1981-4871-aa7e-8b11de: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 650dd621-1bdd-4397-9780-64635d57c51b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen c295497a-fc2a-43be-ad45-606652 (Blood Derived Normal), aliquot c295497a-fc2a-43be-ad45-606652_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cfb8423c-216e-4d7c-8401-c8261d37718f

The open-access MAF lists 96 somatic variants for this specimen: 71 protein-altering or splice-affecting, 16 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 16, Intron 7, Frame Shift Del 3, Splice Site 2, Splice Region 2, In Frame Del 2, Nonsense Mutation 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM8 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1023195047, COSV69864780; called by muse, mutect2, varscan2
- ANK1 | c.2244C>A p.D748E | Missense Mutation (SNP) | VAF 78/409 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as COSV99224650; called by muse, mutect2, varscan2
- CHGA | c.215A>G p.H72R | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1463472942, COSV53664103; called by muse, mutect2, varscan2
- CNTFR | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs753791400, COSV63634323; called by muse, mutect2, varscan2
- COL7A1 | c.3850G>A p.G1284S | Missense Mutation (SNP) | VAF 73/267 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as rs764353299; called by muse, mutect2, varscan2
- COPS6 | c.793C>T p.H265Y | Missense Mutation (SNP) | VAF 109/410 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.836); catalogued as rs1168375830, COSV57999254; called by muse, mutect2, varscan2
- CSMD3 | c.6085T>C p.F2029L (on ENST00000297405 / NM_001363185.1; = p.F1925L on NM_052900.3) | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV52270420; called by muse, mutect2, varscan2
- FOCAD | c.1583G>A p.R528Q | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.987); catalogued as rs778930504; called by muse, mutect2, varscan2
- FSIP2 | c.20420C>T p.S6807F | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0.035); catalogued as COSV58104228; called by muse, mutect2, varscan2
- GRIK3 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.696); catalogued as COSV66140545; called by muse, mutect2, varscan2
- HNRNPD | c.737A>G p.N246S | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.439); catalogued as rs369442299; called by muse, mutect2, varscan2
- KCNA5 | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 148/661 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV52905094; called by muse, mutect2, varscan2
- LRRC24 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs1359250100; called by muse, mutect2, varscan2
- MGAM2 | c.4923G>A p.T1641= | Splice Region (SNP) | VAF 7/180 reads (4%) | catalogued as rs764964625; called by muse, mutect2
- MYOD1 | c.49G>T p.D17Y | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as rs1384154825, COSV51452550; called by muse, mutect2, varscan2
- NOTCH2 | c.3995G>A p.R1332H | Missense Mutation (SNP) | VAF 65/382 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs587609362; ClinVar: not provided; called by muse, mutect2, varscan2
- POM121L12 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 90/356 reads (25%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.025); catalogued as rs202031574, COSV68692498; called by muse, mutect2, varscan2
- PTPRD | c.731A>G p.N244S | Missense Mutation (SNP) | VAF 17/186 reads (9%) | SIFT tolerated (0.94); PolyPhen benign (0.028); catalogued as rs781546140; called by muse, mutect2
- RPGR | c.1261T>A p.S421T | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.53); catalogued as COSV100139847; called by muse, mutect2, varscan2
- RYR1 | c.1930C>T p.R644C | Missense Mutation (SNP) | VAF 40/451 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs760672188, COSV62089135; called by muse, mutect2
- SLC9A9 | c.755+1G>T p.X252_splice | Splice Site (SNP) | VAF 18/271 reads (7%) | catalogued as COSV57228147; called by muse, mutect2
- THEMIS | c.989G>C p.R330T | Missense Mutation (SNP) | VAF 68/215 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64072833; called by muse, mutect2, varscan2
- THSD7B | c.4276C>A p.P1426T (on ENST00000272643; = p.P1424T on NM_001316349.2) | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55654881, COSV99743811; called by muse, mutect2
- TMPRSS11A | c.5T>C p.M2T | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs746187334; called by muse, mutect2, varscan2
- TP53 | c.575del p.Q192Rfs*55 | Frame Shift Del (DEL) | VAF 316/598 reads (53%) | catalogued as COSV52839714, COSV53416426; called by mutect2, pindel, varscan2
- ZNF629 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 46/82 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1413598369; called by muse, mutect2, varscan2
- ALDH1B1 | c.1150_1161del p.L384_G387del | In Frame Del (DEL) | VAF 105/287 reads (37%) | called by mutect2, pindel, varscan2
- ANO3 | c.1537C>T p.L513F | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- ATP8B2 | c.1041G>T p.E347D (on ENST00000672630; = p.E314D on NM_001005855.2) | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.017); called by mutect2, varscan2
- CST11 | c.280T>C p.C94R | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DISP2 | c.1705A>T p.S569C | Missense Mutation (SNP) | VAF 72/285 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DPYSL5 | c.1201G>T p.D401Y | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF2S3 | c.577G>T p.D193Y | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FEZF1 | c.1400A>T p.Q467L | Missense Mutation (SNP) | VAF 22/269 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.092); called by muse, mutect2
- FUS | c.485A>G p.N162S | Missense Mutation (SNP) | VAF 68/232 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GABRG1 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- HLA-C | c.4C>T p.R2W | Missense Mutation (SNP) | VAF 110/173 reads (64%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- HMCN2 | c.11107G>T p.A3703S | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- HOXB6 | c.493_528del p.F165_R176del | In Frame Del (DEL) | VAF 88/571 reads (15%) | called by mutect2, pindel
- IL25 | c.296A>T p.N99I | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- LSM11 | c.586del p.M196Wfs*15 | Frame Shift Del (DEL) | VAF 17/91 reads (19%) | called by mutect2, pindel, varscan2
- MARF1 | c.5022_5050del p.P1675Lfs*2 | Frame Shift Del (DEL) | VAF 17/90 reads (19%) | called by mutect2, pindel, varscan2
- NBEA | c.892A>C p.N298H | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, varscan2
- OR13D1 | c.224G>T p.S75I | Missense Mutation (SNP) | VAF 118/423 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- OVCH1 | c.2906G>C p.R969T | Missense Mutation (SNP) | VAF 63/244 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- PCLO | c.9051A>C p.E3017D | Missense Mutation (SNP) | VAF 68/279 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PKD1L3 | c.2696A>C p.Q899P | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PLCB1 | c.677A>G p.D226G | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- PPP1R2C | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 75/433 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- RADX | c.2229G>T p.K743N | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- RALGAPA2 | c.3814G>T p.V1272L | Missense Mutation (SNP) | VAF 70/189 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SAR1A | c.136A>T p.K46* | Nonsense Mutation (SNP) | VAF 10/181 reads (6%) | called by muse, mutect2
- SEMA6C | c.457-1G>T p.X153_splice | Splice Site (SNP) | VAF 57/157 reads (36%) | called by muse, mutect2, varscan2
- SFPQ | c.1718G>A p.R573K | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SGO2 | c.1223A>T p.K408I | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- SNX17 | c.209C>G p.A70G | Missense Mutation (SNP) | VAF 34/247 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPHKAP | c.2874G>C p.W958C | Missense Mutation (SNP) | VAF 47/194 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPRR1A | c.205G>T p.V69L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TBC1D32 | c.2491G>C p.D831H | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TCN2 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 73/207 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- TCN2 | c.56A>G p.E19G | Missense Mutation (SNP) | VAF 74/203 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- TFR2 | c.1683G>T p.V561= | Splice Region (SNP) | VAF 163/531 reads (31%) | called by mutect2, varscan2
- TOB1 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM50 | c.1403T>A p.M468K | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.151); called by muse, mutect2
- TTC13 | c.1259A>G p.Q420R | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- UBE2NL | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 85/196 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- XPO7 | c.3096G>C p.Q1032H | Missense Mutation (SNP) | VAF 56/96 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- ZFP37 | c.1307A>C p.N436T | Missense Mutation (SNP) | VAF 111/289 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ZNF420 | c.334A>T p.I112F | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- ZNF638 | c.5584C>G p.L1862V | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF761 | c.391G>C p.A131P | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- CDK2 | c.678G>T p.V226= | Silent (SNP) | VAF 151/322 reads (47%) | called by muse, mutect2, varscan2
- CNKSR2 | c.480C>A p.V160= | Silent (SNP) | VAF 6/43 reads (14%) | called by muse, varscan2
- CXCR5 | c.864G>A p.K288= | Silent (SNP) | VAF 60/188 reads (32%) | called by muse, mutect2, varscan2
- DHX40 | c.102C>A p.I34= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- FAT3 | c.1476A>G p.L492= | Silent (SNP) | VAF 44/289 reads (15%) | called by muse, mutect2, varscan2
- FOXC1 | c.951G>T p.L317= | Silent (SNP) | VAF 19/80 reads (24%) | called by muse, mutect2, varscan2
- GRM5 | c.465C>A p.A155= | Silent (SNP) | VAF 84/416 reads (20%) | catalogued as COSV59603941; called by mutect2, varscan2
- PDZD8 | c.48C>T p.F16= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs1161747721; called by muse, mutect2, varscan2
- RPS6KA2 | c.1068G>T p.T356= | Silent (SNP) | VAF 30/138 reads (22%) | called by muse, mutect2, varscan2
- SALL1 | c.3270C>T p.N1090= | Silent (SNP) | VAF 106/750 reads (14%) | catalogued as rs143637930, COSV99171601; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC4A2 | c.1930C>T p.L644= | Silent (SNP) | VAF 16/350 reads (5%) | called by muse, mutect2
- SUMF2 | c.87C>T p.P29= (on ENST00000652303; = p.P10= on NM_015411.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 71/250 reads (28%) | catalogued as COSV51907677; called by muse, mutect2, varscan2
- TSKS | c.24G>T p.T8= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV55875354; called by mutect2, varscan2
- TSPYL6 | c.303C>A p.A101= | Silent (SNP) | VAF 63/449 reads (14%) | called by muse, mutect2, varscan2
- WDHD1 | c.1137T>C p.D379= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs1452028403; called by muse, mutect2, varscan2
- ZNF565 | c.177A>G p.E59= (on ENST00000355114; = p.E19= on NM_152477.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 29/195 reads (15%) | catalogued as rs750216921; called by muse, mutect2, varscan2
- AC109583.1 | c.-542-13745C>A | Intron (SNP) | VAF 44/151 reads (29%) | called by muse, mutect2, varscan2
- AC109583.1 | c.-1319+446C>G | Intron (SNP) | VAF 13/110 reads (12%) | called by muse, mutect2, varscan2
- BAGE2 | n.20_29del | RNA (DEL) | VAF 13/76 reads (17%) | called by mutect2, pindel, varscan2
- CARS2 | c.1417-98C>T | Intron (SNP) | VAF 69/261 reads (26%) | catalogued as rs373546015; called by muse, mutect2, varscan2
- COBL | c.1096+19768C>T | Intron (SNP) | VAF 43/301 reads (14%) | called by muse, mutect2, varscan2
- DMD | c.31+83143A>G | Intron (SNP) | VAF 27/141 reads (19%) | called by muse, mutect2, varscan2
- RGR | c.80-24G>A | Intron (SNP) | VAF 48/360 reads (13%) | called by muse, mutect2, varscan2
- TIMP1 | c.-9+63_-9+70del | Intron (DEL) | VAF 9/42 reads (21%) | called by mutect2, pindel, varscan2
- UCP3 | c.*29C>T | 3'UTR (SNP) | VAF 36/303 reads (12%) | catalogued as rs1193411809; called by muse, mutect2, varscan2
